Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4710, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4710-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1:

KIDNEY, RIGHT, RADICAL NEPHRECTOMY –

- A. A. RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 3 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 10.6 cm.
- D. THE NEOPLASM EXTENDS OUTSIDE THE RENAL CAPSULE INTO THE PERINEPHRIC FAT.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. UPPER POLE SOFT TISSUE RESECTION MARGIN IS INVOLVED BY NEOPLASM (ALSO SEE PART 2).
- G. NON-NEOPLASTIC KIDNEY ADJACENT TO TUMOR SHOWS MILD INTERSTITIAL CHRONIC INFLAMMATION, MODERATE ARTERIAL AND ARTERIOLAR SCLEROSIS.
- H. TNM STAGE: pT3a NX MX.

PART 2:

SOFT TISSUE, RIGHT UPPER POLE MARGIN, RESECTION –

- A. RENAL CELL CARCINOMA WITH FAT INVASION.
- B. MARGIN IS INVOLVED BY CARCINOMA (SEE COMMENT).

PART 3:

ADRENAL GLAND, LEFT, ADRENALECTOMY (31.5 GRAMS) –

- A. ADRENOCORTICAL ADENOMA (2.0 CM).
- B. NO INVOLVEMENT BY RENAL CELL CARCINOMA.

COMMENT:

Grossly and microscopically, the tumor shows extracapsular extension at upper pole with positive margin at disrupted edge in part 1. Upper pole margin received separately in Part 2 shows the margin involved by cauterized tumor.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:	Radical nephrectomy
LATERALITY:	Right
TUMOR SITE:	Upper pole
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 10.6 cm Additional dimensions: 8.0 x 7.5 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor extension into perinephric tissues Tumor extension beyond Gerota's fascia
HISTOLOGIC TYPE:	Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G3
PATHOLOGIC STAGING (pTNM):	pT3a pNX Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0 pMX
MARGINS:	Margin(s) involved by invasive carcinoma
ADRENAL GLAND:	Uninvolved by tumor
VENOUS (LARGE VESSEL) INVASION (V):	Absent
LYMPHATIC (SMALL VESSEL) INVASION (L):	Absent
ADDITIONAL PATHOLOGIC FINDINGS:	Inflammation (type): chronic Other: moderate arterial and arteriolar sclerosis

Source: NCI Genomic Data Commons file 0b05dac0-7b7f-41a4-a939-3c7d238fe18a (TCGA-B0-4710.A31FF26A-126F-4AC7-9251-9BBA3E06C03A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).